Somatic mutation profile of tumor specimen 0DNRUV from CCDI case PBCBTR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.8 years (669 days).
Specimen 0DNRUV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81595d66-fb5f-4db3-af54-9c662c825e70.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNRTQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3344f339-3094-4f1d-87d1-ad78c37b594f

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 1, Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PLCB3 | c.3166C>T p.R1056W | Missense Mutation (SNP) | VAF 159/322 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs375052596; called by muse, mutect2, varscan2
- CD300C | c.627G>T p.Q209H | Missense Mutation (SNP) | VAF 62/720 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- CSMD1 | c.8587C>A p.P2863T (on ENST00000520002; = p.P2862T on NM_033225.6) | Missense Mutation (SNP) | VAF 234/796 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- SLC5A7 | c.1672A>T p.T558S | Missense Mutation (SNP) | VAF 38/1522 reads (2%) | SIFT tolerated (0.25); PolyPhen benign (0.009); called by muse, mutect2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 46/1104 reads (4%) | called by muse, mutect2
- ALAD | c.114-46G>A | Intron (SNP) | VAF 28/628 reads (4%) | catalogued as COSV99475098; called by muse, mutect2
- ESS2 | c.*2865T>C | 3'UTR (SNP) | VAF 79/213 reads (37%) | called by muse, mutect2, varscan2
